CCDI case PBBRVM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e0ecf8dd-01e6-4764-8646-6c6460b40c8b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,553 days).

Biospecimens (3 samples)
- Sample 0DF86K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF86L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF86M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
